Somatic mutation profile of tumor specimen C3L-00994-04 (aliquot CPT0169730006) from CPTAC case C3L-00994, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 50.0 years (18,263 days).
Specimen C3L-00994-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c8dc2d5-eba9-4992-b384-28dd61fa4f44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00994-31 (Blood Derived Normal), aliquot CPT0167170002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb8e8e6a-834c-40e9-a7df-7bd08a580a4e

The open-access MAF lists 83 somatic variants for this specimen: 59 protein-altering or splice-affecting, 10 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 10, Intron 6, Nonsense Mutation 5, RNA 4, 3'UTR 3, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 15/210 reads (7%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADRA2C | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.277); catalogued as rs564653582; called by muse, mutect2, varscan2
- ASXL1 | c.2548G>T p.E850* | Nonsense Mutation (SNP) | VAF 22/205 reads (11%) | catalogued as rs914002110, COSV60116228; called by muse, mutect2, varscan2
- BSCL2 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.92); catalogued as rs143017094; called by muse, mutect2
- CACNA1A | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1365721398, COSV64200218; ClinVar: uncertain significance; called by muse, mutect2
- CCDC120 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs782537429, COSV99059311; called by muse, mutect2, varscan2
- DOCK1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as rs755068207; called by muse, mutect2, varscan2
- EPHA8 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51263365, COSV51273592; called by muse, mutect2
- FAM135B | c.2343G>T p.E781D | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV52745212; called by muse, mutect2
- GJA1 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.88); catalogued as rs778383309; called by muse, mutect2
- GOLGA8T | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 42/470 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1359274251; called by muse, mutect2, varscan2
- NOTCH3 | c.763G>A p.V255I | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1160655218, COSV54632130; called by muse, mutect2
- NWD1 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.637); catalogued as rs867793000; called by muse, mutect2
- OR2M2 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.33); catalogued as CM1212891, COSV62899056; called by muse, mutect2
- PCDH1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746686590; called by muse, mutect2, varscan2
- PLAAT4 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 36/286 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV55374242; called by muse, mutect2, varscan2
- PTCH1 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs745669155; ClinVar: uncertain significance; called by muse, mutect2
- PTK2 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61793472; called by muse, mutect2, varscan2
- RAB19 | c.166G>A p.V56M | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); catalogued as rs369833403; called by muse, mutect2
- TBL1X | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs779139555, COSV54275522; called by muse, mutect2, varscan2
- TP63 | c.627C>G p.C209W | Missense Mutation (SNP) | VAF 20/235 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53207574; called by muse, mutect2
- USP35 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 80/309 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as rs1380102851; called by muse, mutect2, varscan2
- WNT9A | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 33/422 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs201136374; called by muse, mutect2
- ZNF536 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 16/194 reads (8%) | catalogued as COSV100834845; called by muse, mutect2
- ZNF735 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70034688; called by muse, mutect2
- AC011479.1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 22/277 reads (8%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- AHNAK | c.12322C>T p.P4108S | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- APOL3 | c.846T>G p.N282K (on ENST00000349314 / NM_145640.2; = p.N211K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2
- ARL6IP4 | c.316G>C p.D106H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ATP2B3 | c.2247G>T p.Q749H | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CCAR2 | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DNAH5 | c.11764G>A p.G3922S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAJB11 | c.827A>T p.D276V | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2
- DST | c.19013C>G p.S6338* (on ENST00000361203 / NM_001374722.1; = p.S4035* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 6/111 reads (5%) | called by muse, mutect2
- ELAVL2 | c.289A>C p.I97L | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- EPC2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- ESR1 | c.395T>A p.L132Q | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- F2R | c.956dup p.C320Lfs*58 | Frame Shift Ins (INS) | VAF 55/359 reads (15%) | called by mutect2, pindel, varscan2
- FAM114A2 | c.1444A>G p.I482V | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.031); called by muse, mutect2
- FAM193B | c.1456A>G p.I486V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2
- FOXC2 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRAT2 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- GALNT17 | c.241T>C p.L81= | Splice Region (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- GET4 | c.730C>A p.L244M | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- GFM2 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- IDH1 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- IGF2BP1 | c.1127T>C p.F376S | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- LCP1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0.271); called by muse, mutect2
- MAST1 | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2
- MAST1 | c.94A>G p.S32G | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2
- POU5F1B | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 39/498 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYBU | c.455G>A p.S152N (on ENST00000276646 / NM_001099754.2; = p.S151N on NM_017786.6) | Missense Mutation (SNP) | VAF 30/241 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- SYCP2L | c.1717C>G p.P573A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TMEM164 | c.782C>T p.T261I (on ENST00000372068 / NM_032227.4; = p.T112I on NM_017698.2) | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- UBR5 | c.4753C>T p.H1585Y | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); called by muse, mutect2
- UGT8 | c.385A>G p.K129E | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USH2A | c.9856C>G p.L3286V | Missense Mutation (SNP) | VAF 30/420 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- VMP1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF721 | c.1864A>G p.I622V (on ENST00000338977; = p.I634V on NM_133474.4) | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- CTSE | c.888C>T p.S296= (on ENST00000360218; = p.S291= on NM_001910.4) | Silent (SNP) | VAF 20/276 reads (7%) | called by muse, mutect2
- EYA1 | c.1632G>A p.R544= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV58158917; called by muse, mutect2
- PROM1 | c.2058T>C p.L686= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- RAB1B | c.333C>T p.S111= | Silent (SNP) | VAF 24/306 reads (8%) | catalogued as rs772077017, COSV61012724; called by muse, mutect2
- SALL3 | c.2502C>G p.P834= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- SPTBN5 | c.6195C>T p.L2065= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as rs775524973; called by muse, mutect2, varscan2
- TEX15 | c.4794G>A p.V1598= (on ENST00000256246; = p.V1981= on NM_001350162.2) | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- TLL2 | c.2433C>A p.G811= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- TRPM2 | c.3546G>A p.E1182= | Silent (SNP) | VAF 35/293 reads (12%) | called by muse, mutect2, varscan2
- WHRN | c.1110C>T p.D370= | Silent (SNP) | VAF 24/478 reads (5%) | catalogued as rs768344109, COSV54333983; called by muse, mutect2
- ABCC6P1 | n.618G>A | RNA (SNP) | VAF 34/474 reads (7%) | called by muse, mutect2
- ATG4B | c.1108+132C>T | Intron (SNP) | VAF 7/103 reads (7%) | catalogued as rs1283231327; called by muse, mutect2
- CABP1 | c.655-3714G>C | Intron (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- CINP | c.7+204A>C | Intron (SNP) | VAF 14/98 reads (14%) | called by muse, mutect2, varscan2
- GGA2 | c.*2255G>C | 3'UTR (SNP) | VAF 9/147 reads (6%) | called by muse, mutect2
- GP6 | c.*502C>T | 3'UTR (SNP) | VAF 31/432 reads (7%) | catalogued as rs778801507, COSV59977773; called by muse, mutect2
- GUSBP4 | n.296A>G | RNA (SNP) | VAF 66/558 reads (12%) | called by muse, mutect2, varscan2
- LINC01621 | n.490G>A | RNA (SNP) | VAF 19/160 reads (12%) | catalogued as rs1490763015; called by muse, mutect2, varscan2
- PEAK3 | c.*2C>G | 3'UTR (SNP) | VAF 7/84 reads (8%) | catalogued as rs1228444379; called by muse, mutect2
- PLEKHM1P1 | n.1681G>T | RNA (SNP) | VAF 29/406 reads (7%) | called by muse, mutect2, varscan2
- TTYH3 | c.124-1023A>T | Intron (SNP) | VAF 35/163 reads (21%) | called by muse, mutect2, varscan2
- VEZT | c.-3A>G | 5'UTR (SNP) | VAF 12/189 reads (6%) | called by muse, mutect2
- VPS35 | c.3+16G>C | Intron (SNP) | VAF 30/220 reads (14%) | called by muse, mutect2, varscan2
- ZSCAN29 | c.1223-72A>T | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
